Somatic mutation profile of tumor specimen TARGET-20-PASBHI-09A (aliquot TARGET-20-PASBHI-09A-02D) from TARGET case TARGET-20-PASBHI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.0 years (2,201 days).
Specimen TARGET-20-PASBHI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d2e5052-9ecb-4c92-9380-288996533788.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASBHI-14A (Bone Marrow Normal), aliquot TARGET-20-PASBHI-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f31c585-9311-44b9-80c0-7d5b00309a42

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2466T>G p.N822K | Missense Mutation (SNP) | VAF 62/208 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913514, COSV55387147, COSV55389584, COSV55431266; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- P2RY2 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 45/106 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as rs1292801922, COSV60776120; called by muse, mutect2, varscan2
- TP53TG5 | c.123G>A p.T41= | Splice Region (SNP) | VAF 48/120 reads (40%) | catalogued as rs767432249, COSV65577396; called by muse, mutect2, varscan2
- AXIN1 | c.395dup p.N133Efs*19 | Frame Shift Ins (INS) | VAF 68/189 reads (36%) | called by mutect2, pindel, varscan2
- AXIN1 | c.2463-15_2463-14insGGA | Intron (INS) | VAF 23/76 reads (30%) | called by mutect2, pindel, varscan2
